Gene-level copy-number profile of tumor specimen TCGA-Z6-AAPN-01A from TCGA case TCGA-Z6-AAPN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 57.3 years (20,926 days).
Specimen TCGA-Z6-AAPN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.73dbe22b-f8a6-439d-b34d-7917b3712cf1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z6-AAPN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54a8ae54-0a30-4200-be15-21800100b9b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 2,046; copy number 2: 25,789; copy number 3: 17,843; copy number 4: 8,564; copy number 5: 4,164; copy number 6: 698; copy number 7: 191; copy number 8: 41; copy number 9: 66; copy number 10: 47; copy number 11: 40; copy number 12: 4; copy number 16: 71; copy number 19: 115; copy number 25: 8; copy number 31: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z6-AAPN-01A-11D-A402-01): tumor purity 0.35, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,786,927–29,826,711, 118 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,442 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:17,308,195–20,718,017, 75 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr1:30,013,952–31,791,322, 43 genes, copy number 5: LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2.
- chr1:94,974,405–96,022,890, 17 genes, copy number 6 (within-gene range 3–6): ALG14, ALG14-AS1, TLCD4, TLCD4-RWDD3, AC092802.3, Y_RNA, AC092802.1, RWDD3, AC092802.2, AC092802.4, LINC01760, LINC01650, AL445218.1, LINC01761, LINC02607, AL683887.1, LINC02790.
- chr1:99,472,332–103,108,872, 62 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:143,343,180–174,090,474, 1,111 genes, copy number 5 (broad region; genes not listed).
- chr2:90,209,873–114,420,302, 525 genes, copy number 5 (broad region; genes not listed).
- chr2:173,075,435–179,934,538, 151 genes, copy number 5–9 (broad region; genes not listed).
- chr2:186,032,884–186,422,432, 1 gene, copy number 7 (within-gene range 4–7): LINC01473.
- chr2:186,261,419–187,565,760, 16 genes, copy number 7: RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI.
- chr2:187,825,341–187,826,449, 1 gene, copy number 7: ST13P2.
- chr2:189,441,446–189,784,364, 13 genes, copy number 8: WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1.
- chr5:58,198–1,816,048, 67 genes, copy number 11–19 (broad region; genes not listed).
- chr5:8,207,019–26,013,025, 254 genes, copy number 7–31 (within-gene range 2–31) (broad region; genes not listed).
- chr5:66,298,394–71,567,820, 100 genes, copy number 5 (broad region; genes not listed).
- chr5:89,581,209–94,618,597, 53 genes, copy number 5 (within-gene range 3–5): LINC02161, AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, AC093298.2, PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1, KIAA0825.
- chr5:127,703,389–128,083,172, 4 genes, copy number 12 (within-gene range 2–12): CCDC192, CUL1P1, AC068658.1, LINC01184.
- chr6:47,477,243–48,214,794, 15 genes, copy number 6: AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr7:70,972–55,678,490, 949 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:78,268,637–89,415,071, 167 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–6,507,054, 115 genes, copy number 5–7 (broad region; genes not listed).
- chr9:6,542,094–6,542,353, 1 gene, copy number 7: RN7SL25P.
- chr12:66,767–20,916,911, 591 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:20,845,065–20,845,260, 1 gene, copy number 5: AC011604.1.
- chr12:37,575,587–46,373,778, 117 genes, copy number 6 (broad region; genes not listed).
- chr12:46,384,233–46,407,166, 3 genes, copy number 6: AC025031.1, AC025031.4, AC025031.5.
- chr12:121,209,861–133,214,832, 369 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–20,232,365, 67 genes, copy number 6 (broad region; genes not listed).
- chr13:20,433,778–20,433,846, 1 gene, copy number 6: MIR4499.
- chr13:34,942,287–35,699,938, 6 genes, copy number 6 (within-gene range 4–6): NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445.
- chr15:31,475,398–44,415,758, 346 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr18:24,113,637–27,795,637, 67 genes, copy number 5 (broad region; genes not listed).
- chr18:27,954,519–27,963,687, 1 gene, copy number 5: AC110015.1.
- chr18:77,421,619–80,247,514, 58 genes, copy number 5: AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr20:8,831,186–13,996,443, 67 genes, copy number 5–8 (broad region; genes not listed).
- chr20:14,003,508–14,636,524, 8 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1.

Autosomal genes at a single copy (total copy number 1): 2,046. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
